Surgical pathology report (de-identified scan), TCGA case TCGA-12-3653, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Duke, specimen TCGA-12-3653-01A (Primary Tumor).

[page 1 of 3]
Patient: [REDACTED]

AP Surgical Pathology: Additional Info [REDACTED] Acc# [REDACTED]

Surg Path

CLINICAL HISTORY:

Right temporal brain tumor

GROSS EXAMINATION:

A. "Brain tissue (AF1)", received fresh for frozen section is a 2 x 1 x 0.8 cm fragment of focally hemorrhagic red-tan soft tissue. A representative section is frozen as AF1, the frozen remnant is submitted in A1. Additional representative tissue is submitted in block A2, with a small portion retained in formalin.

B. "Brain tissue (BF1)", received fresh for frozen section is a 5 x 4.5 x 3.5 cm portion of tan-brown brain tissue with necrotic, hemorrhagic areas adjacent to grossly uninvolved brain tissue. A representative section of the necrotic area is frozen as BF1, the frozen remnant submitted in B1. Additional abnormal areas are submitted in B2-5, with the majority of the specimen retained in formalin.

INTRA OPERATIVE CONSULTATION:

- A. "Brain tissue":AF1- high grade glioma [REDACTED].
B. "Brain tissue":BF1- high grade glioma [REDACTED].

MICROSCOPIC EXAMINATION:

Microscopic examination shows brain infiltrated by a malignant astrocytic neoplasm characterized by cytologic pleomorphism, mitotic figures, microvascular changes and pseudopalisading necrosis.

DIAGNOSIS:

- A. "BRAIN TISSUE (AF1)" (CRANIOTOMY):

GLIOBLASTOMA (WHO GRADE IV).

- B. "BRAIN TISSUE (BF1)" (CRANIOTOMY):

GLIOBLASTOMA (WHO GRADE IV).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

ADDENDUM 1:

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

FISH INTERPRETATION SUMMARY:

CHROMOSOME 7 CENTROMERE - POLYSOMY (88% OF TUMOR CELLS EXHIBIT POLYSOMY)

EGFR - AMPLIFICATION (99% OF TUMOR CELLS EXHIBIT AMPLIFICATION)

CHROMOSOME 10 CENTROMERE - CENTROMERE LOSS (61% OF TUMOR CELLS EXHIBIT LOSS)

PTEN - ALLELIC LOSS (73% OF TUMOR CELLS EXHIBIT LOSS)

[page 2 of 3]
9p21 - LOSS (69% OF TUMOR CELLS EXHIBIT LOSS)

CHROMOSOME 9 CENTROMERE - CENTROMERE LOSS (54% OF TUMOR CELLS EXHIBIT LOSS)

4 OF 4 ABNORMAL MARKERS AND 9P21 EXHIBITS LOSS.

COMMENT: A MULTIVARIATE SURVIVAL ANALYSIS OF [REDACTED] PATIENTS WITH GLIOBLASTOMAS REVEALS THAT THE HAZARD OF SHORT SURVIVAL AMONG PATIENTS WITH 0-2 ABNORMAL MARKERS (OUT OF 4) WAS SIGNIFICANTLY LOWER THAN THAT FOUND WITH PATIENTS WITH 4 ABNORMAL MARKERS EVEN AFTER ADJUSTMENT FOR AGE EFFECT.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED] D.

Electronically signed: [REDACTED]

ADDENDUM 2:

IMMUNOHISTOCHEMICAL LABELING INDEX OF TUMOR CELLS:

TISSUE TYPE: BRAIN TISSUE CONTAINING GLIOBLASTOMA (WHO GRADE IV; [REDACTED])

LEUCOCYTE COMMON ANTIGEN (LCA): 5% OF POSITIVE CELLS.

PROLIFERATION INDEX INTERPRETATION: HIGH PROLIFERATION INDEX (30% OF TUMOR CELLS EXHIBIT STAINING).

MGMT - POSITIVE (25% OF TUMOR CELLS)

EGFR wt - POSITIVE (3+ IN 90% OF TUMOR CELLS)

EGFR vIII - POSITIVE (2+ IN 1% OF TUMOR CELLS)

S6 - POSITIVE (2+ IN 30% OF TUMOR CELLS)

AKT - NEGATIVE (2+ IN 5% OF TUMOR CELLS)

MAPK - POSITIVE (2+ IN 25% OF TUMOR CELLS)

CARBONIC ANHYDRASE IX: POSITIVE FOR EXPRESSION OF CARBONIC ANHYDRASE IX.

VEGF IMMUNOHISTOCHEMISTRY: NEGATIVE (2 x 2% = score 4). Intensity x distribution => 20 is positive.

PDGFR-A IMMUNOHISTOCHEMISTRY: WIDESPREAD (50%) FOR CYTOPLASMIC AND/OR MEMBRANE REACTIVITY.

PDGFR-B IMMUNOHISTOCHEMISTRY: FOCAL (40%) FOR CYTOPLASMIC AND/OR MEMBRANE REACTIVITY.

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED] D.

Electronically signed: [REDACTED]

ADDENDUM 3:

MGMT PROMOTER METHYLATION REAL TIME PCR ANALYSIS

[page 3 of 3]
Received [REDACTED] from [REDACTED] is a copy of an MGMT Promoter Methylation Assay, obtained at the request of [REDACTED], on paraffin block [REDACTED]. The complete report from [REDACTED] is on file in the Image Cytometry Laboratory.

Results:

MGMT promoter methylation NOT identified.

Comment: The specimen is considered negative for MGMT promoter methylation when Methylation Index (MI) is less than 4. MI between 4 and 16 is considered as low level of methylation and should be interpreted with caution since the significance of low level methylation in gliomas is not well understood. MI greater than 16 is considered methylated.

[REDACTED]

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

Electronically signed: [REDACTED]

Performed by: [REDACTED]

Ordering MD: [REDACTED]

Source: NCI Genomic Data Commons file 5f1e3b0e-5d74-4606-9c82-b0c7f30a763e (TCGA-12-3653.B2EA02B9-4F9F-474E-88FE-7306AEAC14EC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).